Surgical pathology report (de-identified scan), TCGA case TCGA-CU-A0YO, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site UNC, specimen TCGA-CU-A0YO-01A (Primary Tumor).

[page 1 of 3]
Case Number :

Collection Date :

Surgical Pathology Report

Diagnosis:

A: Bladder and prostate, cystoprostatectomy

Bladder primary:

Tumor histologic type: urothelial carcinoma

Tumor histology grade (WHO): high grade

Depth of invasion: through muscularis propria into perivesical fat (A11, A26)

Focality of tumor: unifocal

Angiolymphatic invasion: lymphatic invasion present (eg. A10)

Intraepithelial abnormality: not identified

Ureters: not involved, but uretero-vesicular junctions involved bilaterally

Surgical margins:

Ureter, left: negative

Ureter, right: negative

Urethra: positive for prostatic adenocarcinoma (A1, 2 mm diameter) negative for urothelial carcinoma

Paravesicular soft tissue: negative, but close (1 mm to serosal surface (A12))

Other significant findings: prostate adenocarcinoma, see below

Lymph nodes: separately submitted, see specimens B and C

Diagnoses of other organs: see below

AJCC stage (bladder): pT3a pN2 pMx

Prostate primary:

Tumor histologic type: adenocarcinoma

Grade: Gleason score 3+3

Location: unilateral right, estimated more than d of the right lobe involved

Vascular invasion: not identified

Extracapsular extension: not identified

Surgical margins: right distal urethral margin involved (A1)

AJCC stage: pT2b pN0 pMx

B: Lymph nodes, right pelvic, dissection

- Metastatic urothelial carcinoma (7/10), largest metastasis 1.4 cm diameter, without extracapsular extension.

- No metastatic prostatic adenocarcinoma identified.

C: Lymph nodes, left pelvic, dissection

1CB-0-3

carcinoma, urothelial, NOS 8120/3

Site: bladder, NOS C67.9

2/18/11

fr

Dual/Synchronous Primary	Noted	

[page 2 of 3]
- Metastatic urothelial carcinoma (1/3), 2 mm diameter, without extracapsular extension.
- No metastatic prostatic adenocarcinoma identified.

Clinical History:

Gross Description:

Received are three appropriately labeled containers.

Container A:

Specimen fixation: formalin

Type of specimen(s) received: cystectomy

Size of urinary bladder: 13.8 x 11.2 x 4.5 cm overall; The bladder is approximately 8.7 x 0.2 x 4.5 cm.

Orientation: Inking: right prostate=blue, left prostate=black, apex=yellow, posterior peritoneal surface overlying bladder=green.

Tumor size: 4.5 x 1.9 cm

Tumor location: The tumor encompasses the majority of the bladder. The superior/posterior peritoneal surface is firm and lobulated (inked green).

Other mucosal lesions: The trigone is diffusely erythematous.

Gross description of other organs or structures: A 2.5 x 2.0 x 0.5 cm questionable prostate, The gross appearance is not consistent with prostate. However, the requisition is labeled "bladder and prostate." No seminal vesicles or vasa differentia are grossly identified.

Digital photograph taken: no

Tissue submitted for special investigation: yes; Tumor was submitted for Tissue Procurement

Block Summary: (Inking: right prostate=blue, left prostate=black, apex=yellow, superior/posterior peritoneal surface of the bladder=green)

- A1 - right distal urethral margin
- A2 - left distal urethral margin
- A3 - right ureter margin
- A4 - left ureter margin
- A5 - right ureter margin, next cross section
- A6 - left ureter margin, next cross section
- A7 - right ureterovesicular junction
- A8 - left ureterovesicular junction
- A9 - tan mass with respect to green inked peritoneum
- A10 - mass, posterior/dome
- A11-A14 - uninvolved trigone
- A15 - uninvolved right lateral wall
- A16 - uninvolved left lateral wall
- A17,A18 - perpendicular sections of presumed prostate (just inferior to the trigone to the surface of the specimen)
- A19 - perpendicular section of the presumed right side of the prostate
- A20 - perpendicular section of the presumed left side of the prostate
- A21-A24 remainder of right lobe of prostate
- A25-A30 - remainder of left lobe of prostate

Container B is additionally labeled "right pelvic lymph nodes." It holds a 5.5 x 4.0 x 1.0 cm fragment of yellow lobulated adipose tissue which is dissected for lymph nodes. Lymph node candidates are grossly identified ranging from 0.4 cm to 4.1 cm in greatest dimension. Sections are submitted as follows:

[page 3 of 3]
Block summary:

B1,B2 - largest lymph node, bisected
B3-B4 - one lymph node candidate, bisected
B5 - one lymph node candidate, bisected
B6 - four lymph node candidates

Container C is additionally labeled "left pelvic lymph nodes." It holds a 6 x 2 x 1.2 cm fragment of yellow lobulated adipose tissue which is dissected for lymph nodes. Four lymph node candidates are gross identified ranging from 0.5 cm to 4 cm in greatest dimension. Sections are submitted as follows:

C1,C2 - largest lymph node candidate, serially sectioned
C3 - two lymph node candidates

Light Microscopy:

Light microscopic examination is performed

Urothelial carcinoma extends into perivesicle fat in A11, A12, and A26.

Prostatic adenocarcinoma is identified in the R lobe in blocks A1, A19, A22, and A23. called with the unexpected prostatic ACa data

Signature

Attending Pathologist: I have personally conducted the evaluation of the above specimens and have rendered the above diagnosis(es).

Source: NCI Genomic Data Commons file 8bce7c6d-0e0f-4057-8045-85484985d6f2 (TCGA-CU-A0YO.2216705A-2F61-47ED-9E0B-619AE7515C0B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).